Somatic mutation profile of tumor specimen BA2225D (aliquot aq-BA2225D) from BEATAML1.0 case 2188, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.6 years (28,333 days).
Specimen BA2225D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67a4f77b-2be5-46e1-98ee-afd0ae31ffb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2467D (Solid Tissue Normal), aliquot aq-BA2467D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/801bcfa2-bfea-4cbe-a62f-7901817ec0ed

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS5 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.63); catalogued as COSV53185899; called by muse, varscan2
- ANKRD33 | c.501C>A p.S167R (on ENST00000340970 / NM_001304459.2; = p.S292R on NM_182608.4) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.383); catalogued as COSV56605439; called by muse, mutect2
- BMP1 | c.1322A>C p.K441T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.595); catalogued as rs1028028067, COSV60482362; called by muse, mutect2
- DNMT3A | c.1843C>T p.Q615* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as rs768548187, COSV53047246; called by muse, mutect2
- ERMAP | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs200208103; called by muse, mutect2, varscan2
- GPRC6A | c.2239G>T p.G747* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV59956968; called by muse, mutect2
- MPL | c.1896G>C p.W632C | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs753170989, COSV65247217; called by muse, mutect2, varscan2
- MYSM1 | c.2152G>T p.D718Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV68978282; called by muse, mutect2
- NBEAL2 | c.3106G>A p.A1036T | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); catalogued as rs769080091; called by muse, mutect2, varscan2
- NOX5 | c.380C>A p.P127Q | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1406008186; called by muse, mutect2
- ZFHX4 | c.3290T>C p.I1097T | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV50981818, COSV51456374; called by muse, mutect2
- CFAP43 | c.2273C>T p.S758F | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); called by muse, mutect2
- CSMD2 | c.4815G>T p.K1605N | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EZH2 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FYB2 | c.1923A>T p.L641F | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.329); called by muse, mutect2
- GOLIM4 | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- INTS4 | c.12C>G p.H4Q | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MOGAT2 | c.988C>A p.H330N | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); called by muse, mutect2
- PCDH1 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- RGS22 | c.1883C>A p.S628Y | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- SI | c.1163A>T p.D388V | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TCHH | c.2192G>T p.R731L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); called by muse, mutect2
- ZFHX2 | c.5020C>T p.R1674C | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2
- DNAH9 | c.987G>A p.P329= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs200590483, COSV52348086; called by muse, mutect2, varscan2
- INSRR | c.2400C>T p.S800= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1431344962; called by muse, mutect2
- SHANK2 | c.2529G>T p.T843= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as rs782139196; called by muse, mutect2, varscan2
- SOWAHA | c.465G>A p.P155= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- CAV1 | c.30+51T>C | Intron (SNP) | VAF 10/215 reads (5%) | called by muse, mutect2
